Somatic mutation profile of tumor specimen TCGA-2G-AAH4-01A (aliquot TCGA-2G-AAH4-01A-12D-A42Y-10) from TCGA case TCGA-2G-AAH4, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 34.2 years (12,481 days).
Specimen TCGA-2G-AAH4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 713e3a8c-4489-45c3-9bc6-8349cff6841e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAH4-10A (Blood Derived Normal), aliquot TCGA-2G-AAH4-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/285a7341-4141-43a6-972a-38d2bcb910d1

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 5, 3'UTR 1, Splice Region 1, Nonsense Mutation 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA6 | c.731C>T p.T244I | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67586227; called by muse, mutect2, varscan2
- KMT2C | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 67/259 reads (26%) | catalogued as COSV51344483; called by muse, mutect2, varscan2
- ARHGAP1 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BMS1 | c.2509G>C p.D837H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DST | c.13846A>G p.R4616G (on ENST00000361203 / NM_001374722.1; = p.R2204G on NM_015548.5) | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM118B | c.698G>C p.R233T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- MAP3K7 | c.1212C>A p.A404= | Splice Region (SNP) | VAF 57/177 reads (32%) | called by muse, mutect2, varscan2
- ANKRD11 | c.5484G>A p.S1828= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs140164595; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCNB3 | c.2766T>C p.N922= | Silent (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- SOCS3 | c.453G>A p.P151= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs371734270; called by muse, mutect2, varscan2
- TENM4 | c.6546G>A p.K2182= | Silent (SNP) | VAF 54/154 reads (35%) | called by muse, mutect2, varscan2
- ZFP42 | c.72G>A p.G24= | Silent (SNP) | VAF 70/148 reads (47%) | catalogued as rs746539775; called by muse, mutect2, varscan2
- C17orf58 | c.103+78G>C | Intron (SNP) | VAF 74/269 reads (28%) | called by muse, mutect2, varscan2
- ECM1 | c.*8C>T | 3'UTR (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- TRIM53AP | n.704A>T | RNA (SNP) | VAF 8/30 reads (27%) | called by mutect2, varscan2
